Somatic mutation profile of tumor specimen C3L-04505-54 (aliquot CPT0260200002) from CPTAC case C3L-04505, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 45.1 years (16,464 days).
Specimen C3L-04505-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56ce5201-bc4c-4812-a1e4-c4b2d51590ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04505-51 (Buccal Cell Normal), aliquot CPT0260190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63ea1545-105b-46da-a580-a93099ae70c0

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/562 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DUXA | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1228440980, COSV73729900; called by muse, mutect2, varscan2
- KLHDC7B | c.1528C>T p.R510C (on ENST00000395676; = p.R1151C on NM_138433.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750273973, COSV67464640; called by muse, mutect2, varscan2
- NRAP | c.1488G>T p.Q496H (on ENST00000359988 / NM_001322945.2; = p.Q461H on NM_006175.4) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV63489596; called by muse, mutect2
- PCDHB7 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.386); catalogued as rs782021995, COSV50793324; called by muse, mutect2, varscan2
- SNAPC1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs771775109; called by muse, mutect2, varscan2
- COL12A1 | c.1712T>G p.I571S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM72A | c.356-1G>A p.X119_splice | Splice Site (SNP) | VAF 82/194 reads (42%) | called by muse, mutect2, varscan2
- HMGB3 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by mutect2, varscan2
- BDKRB2 | c.924C>T p.R308= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV60014225; called by muse, mutect2, varscan2
